Surgical pathology report (de-identified scan), TCGA case TCGA-S7-A7WM, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University Hospital Motol, specimen TCGA-S7-A7WM-01A (Primary Tumor).

Gross

Right adrenal gland with a tumor weighing 48 g and with dimensions 69x50x30 mm. On cut, ovoid encapsulated grey-pink tumor with soft consistency. Material was procured in 6 blocks.

Micro:

Solidly alveolarly shaped pheochromocytoma with focal fibrotization and multiple cellular atypias, in all examined excisions with fibrous capsule and with remnants of the adrenocortical structures on the periphery. In block 3D, penetration through adrenocortical structures and initial invasion through the fibrous adrenal capsule were found. No spread in to the surrounding adipose tissue was found.

Staining for S100 protein was variably positive, in less differentiated parts of the tumor in one cut rarefaction or even vanishing.

MIB1 <1% (positive control in the cut with adrenal cortex remnants)

PASS:

Large nests or diffuse growth (>10% of tumor volume) 2

Central (middle of large nests) or confluent tumor necrosis

High cellularity 2

Cellular monotony

Tumor cell spindling (even if focal)

Mitotic figures >3/10 HPF

Atypical mitotic figure(s)

Extension into adipose tissue

Vascular invasion

Capsular invasion 1

Profound nuclear pleomorphism 1

Nuclear hyperchromasia 1

Total 7

Procurement date:

Confirmation date:

ICD-O-3
Pheochromocytoma malignant NOS
8700/3
Site @ Adrenal gland NOS
C74.9
JW 10/9/13

QAA Discrepancy		✓

Source: NCI Genomic Data Commons file f272a7f6-4a25-47db-ae78-22f067f3db5a (TCGA-S7-A7WM.AEB0DE75-5B02-4A31-BD92-7354BAF806FB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).